Somatic mutation profile of tumor specimen TCGA-OR-A5L5-01A (aliquot TCGA-OR-A5L5-01A-11D-A29I-10) from TCGA case TCGA-OR-A5L5, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 77.4 years (28,270 days).
Specimen TCGA-OR-A5L5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f26d582-0617-4894-b5c6-8bbd7f0e0337.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5L5-10A (Blood Derived Normal), aliquot TCGA-OR-A5L5-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a8698a3-f143-4665-af1a-d2b38f597a48

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 1, 5'Flank 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MXRA5 | c.3428G>C p.S1143T | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761991782; called by muse, mutect2, varscan2
- SZT2 | c.2956G>A p.V986I | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs531185509, COSV65172984; called by muse, mutect2, varscan2
- AUTS2 | c.886A>G p.K296E | Missense Mutation (SNP) | VAF 54/101 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- KLHL24 | c.1352G>T p.S451I | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- L1TD1 | c.1145C>T p.S382F | Missense Mutation (SNP) | VAF 15/199 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2
- LRCH4 | c.947A>T p.E316V | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2
- MYO1G | c.1420_1428del p.S474_G476del | In Frame Del (DEL) | VAF 59/128 reads (46%) | called by mutect2, pindel, varscan2
- RSF1 | c.1675A>G p.T559A | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBA6 | c.1416C>A p.G472= | Silent (SNP) | VAF 23/170 reads (14%) | called by muse, mutect2, varscan2
- H2BC15 | chr6:27838660 ins CATGCCC | 5'Flank (INS) | VAF 52/165 reads (32%) | called by mutect2, varscan2
- PTPDC1 | c.83-572A>T | Intron (SNP) | VAF 15/111 reads (14%) | called by muse, mutect2, varscan2
